Somatic mutation profile of tumor specimen TARGET-10-PAREEX-09A (aliquot TARGET-10-PAREEX-09A-01D) from TARGET case TARGET-10-PAREEX, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 7.7 years (2,798 days).
Specimen TARGET-10-PAREEX-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1ec4da64-4ffc-4aee-9b2d-b316235e5794.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAREEX-10A (Blood Derived Normal), aliquot TARGET-10-PAREEX-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/eba7fc69-2779-4b72-a92b-2e0cdd544e9d

The open-access MAF lists 18 somatic variants for this specimen: 12 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 5, Intron 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 29/65 reads (45%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ATP2B3 | c.2221C>T p.R741C | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.209); catalogued as rs1215901845, COSV54841395; called by muse, mutect2, varscan2
- GDF10 | c.814G>A p.G272R | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.721); catalogued as rs782623944; called by muse, mutect2, varscan2
- LRRC30 | c.781G>A p.A261T | Missense Mutation (SNP) | VAF 35/103 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV67301533; called by muse, mutect2, varscan2
- MEOX1 | c.452G>A p.R151Q | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as rs777237192; called by muse, mutect2, varscan2
- NLRC5 | c.784C>T p.R262C | Missense Mutation (SNP) | VAF 43/87 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as rs1390413247, COSV52649633; called by muse, mutect2, varscan2
- OXTR | c.866C>T p.T289M | Missense Mutation (SNP) | VAF 33/84 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.832); catalogued as rs1244817296, COSV57478421, COSV57479410; called by muse, mutect2, varscan2
- PCDH19 | c.3340C>T p.R1114C (on ENST00000373034 / NM_001184880.2; = p.R1066C on NM_020766.3) | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.649); catalogued as rs763455091; called by muse, mutect2, varscan2
- ROBO1 | c.3908G>A p.R1303Q | Missense Mutation (SNP) | VAF 36/61 reads (59%) | SIFT tolerated (0.23); PolyPhen benign (0.209); catalogued as rs761320548; called by muse, varscan2
- SMAD9 | c.283G>A p.V95M | Missense Mutation (SNP) | VAF 31/58 reads (53%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.995); catalogued as COSV63204678; called by muse, mutect2, varscan2
- TTN | c.17606C>T p.T5869M (on ENST00000591111; = p.T4942M on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 45/110 reads (41%) | PolyPhen possibly damaging (0.721); catalogued as rs200359082; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- IFITM1 | c.39_40insG p.P14Afs*51 | Frame Shift Ins (INS) | VAF 52/110 reads (47%) | called by mutect2, varscan2
- EGFLAM | c.462G>A p.S154= | Silent (SNP) | VAF 26/43 reads (60%) | catalogued as rs146327095, COSV59294584; called by muse, mutect2, varscan2
- EXOSC5 | c.651G>A p.S217= | Silent (SNP) | VAF 24/59 reads (41%) | catalogued as rs540292584, COSV55370937; called by muse, mutect2, varscan2
- ROBO1 | c.4002C>A p.A1334= | Silent (SNP) | VAF 46/131 reads (35%) | called by muse, varscan2
- SPTB | c.5127G>A p.K1709= | Silent (SNP) | VAF 62/106 reads (58%) | called by muse, mutect2, varscan2
- UNC13C | c.483A>G p.A161= | Silent (SNP) | VAF 65/133 reads (49%) | catalogued as rs745542322; called by muse, mutect2, varscan2
- POR | c.516+168G>C | Intron (SNP) | VAF 8/27 reads (30%) | catalogued as COSV67516143; called by muse, mutect2, varscan2
